Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGJ, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGJ-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (EC 85%, SE 15%); diameter 3 cm; tumor confined to testis;
no angio-invasion; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

1CD-0-3

germ cell tumor, mixed 9085/3

Site: (L) Testis, NOS C62.9

hw

Source: NCI Genomic Data Commons file e36fb222-3b92-4eee-a5f4-8e868f5e51b4 (TCGA-2G-AAGJ.8BEEA45C-C681-4747-A27B-71759A47E13E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).